CCDI case PBCDKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/011b9ac5-0d15-479d-8edd-1f60bb66d28b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 0.0 years (10 days).

Biospecimens (3 samples)
- Sample 0DPBFE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPBFX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPBGW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
